Somatic mutation profile of tumor specimen MMRF_1677_1_BM_CD138pos (aliquot MMRF_1677_1_BM_CD138pos_T1_KBS5U_L04790) from MMRF case MMRF_1677, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 51.1 years (18,649 days).
Specimen MMRF_1677_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3c6c49e0-8009-4ef3-a20c-26480fd5e2b3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1677_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1677_1_PB_Whole_C3_KBS5U_L04803; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/38f68165-f003-4de9-8631-c60473f72c51

The open-access MAF lists 79 somatic variants for this specimen: 30 protein-altering or splice-affecting, 8 silent, 41 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 28, 3'UTR 24, Intron 9, Silent 8, 3'Flank 3, 5'UTR 3, 5'Flank 2, Frame Shift Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CAMTA1 | c.3110G>A p.R1037H | Missense Mutation (SNP) | VAF 91/155 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs762417443; called by muse, mutect2, varscan2
- CCDC81 | c.1256C>T p.A419V (on ENST00000445632 / NM_001156474.2; = p.A329V on NM_021827.4) | Missense Mutation (SNP) | VAF 16/130 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.058); catalogued as rs766513360, COSV53579586; called by muse, mutect2, varscan2
- DNAH2 | c.845G>A p.R282H | Missense Mutation (SNP) | VAF 58/122 reads (48%) | SIFT tolerated (0.08); PolyPhen benign (0.019); catalogued as rs369805347; called by muse, varscan2
- IGLV3-1 | c.104A>C p.Q35P | Missense Mutation (SNP) | VAF 60/62 reads (97%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs533329143; called by muse, mutect2, varscan2
- IGLV3-19 | c.320A>G p.N107S | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs540401353; called by muse, varscan2
- MUC16 | c.3142A>T p.T1048S | Missense Mutation (SNP) | VAF 47/95 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.096); catalogued as COSV67453729; called by muse, mutect2, varscan2
- MYLK | c.4603G>A p.V1535I | Missense Mutation (SNP) | VAF 33/62 reads (53%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.648); catalogued as rs776503378, COSV60605693; ClinVar: uncertain significance; called by muse, mutect2
- NAP1L3 | c.960G>T p.K320N | Missense Mutation (SNP) | VAF 112/112 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100220577, COSV59073888; called by muse, mutect2, varscan2
- PARP14 | c.3571A>G p.N1191D | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT tolerated (0.17); PolyPhen benign (0.151); catalogued as rs1272811114; called by muse, mutect2, varscan2
- PTPN13 | c.1465C>A p.Q489K | Missense Mutation (SNP) | VAF 60/150 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.255); catalogued as rs774225639; called by muse, mutect2, varscan2
- SDK2 | c.6382C>T p.R2128W | Missense Mutation (SNP) | VAF 53/111 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.952); catalogued as rs781156628; called by muse, mutect2, varscan2
- TENM3 | c.151G>T p.D51Y | Missense Mutation (SNP) | VAF 106/217 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV69304027, COSV69317427; called by muse, mutect2, varscan2
- TNFRSF10C | c.545C>A p.T182K | Missense Mutation (SNP) | VAF 20/100 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.168); catalogued as rs61736404; called by muse, varscan2
- TRIM51 | c.430del p.M144Cfs*15 | Frame Shift Del (DEL) | VAF 40/100 reads (40%) | catalogued as rs763121810; called by mutect2, varscan2
- C2CD6 | c.1319C>G p.T440R | Missense Mutation (SNP) | VAF 74/151 reads (49%) | SIFT tolerated (0.36); PolyPhen benign (0.215); called by muse, mutect2, varscan2
- CATSPERG | c.2556+2T>A p.X852_splice | Splice Site (SNP) | VAF 36/75 reads (48%) | called by muse, mutect2, varscan2
- CEP162 | c.375A>C p.L125F | Missense Mutation (SNP) | VAF 56/264 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- FBXL14 | c.106C>T p.R36W | Missense Mutation (SNP) | VAF 47/97 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, varscan2
- IGHV2-5 | c.182C>G p.P61R | Missense Mutation (SNP) | VAF 19/19 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); called by muse, varscan2
- IGLV3-19 | c.29T>A p.L10H | Missense Mutation (SNP) | VAF 41/105 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, varscan2
- MAGI3 | c.1433A>C p.Q478P | Missense Mutation (SNP) | VAF 87/102 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NAALAD2 | c.1141G>T p.G381W | Missense Mutation (SNP) | VAF 80/325 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NRG2 | c.920G>T p.G307V | Missense Mutation (SNP) | VAF 66/139 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PIEZO1 | c.4813G>C p.D1605H | Missense Mutation (SNP) | VAF 43/113 reads (38%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.621); called by muse, mutect2, varscan2
- RASSF6 | c.707G>A p.R236K (on ENST00000342081 / NM_201431.2; = p.R204K on NM_177532.5) | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.794); called by muse, mutect2, varscan2
- RBMS3 | c.298C>A p.Q100K | Missense Mutation (SNP) | VAF 37/83 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- RNF157 | c.462C>A p.N154K | Missense Mutation (SNP) | VAF 65/133 reads (49%) | SIFT tolerated (0.31); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- SMIM20 | c.403G>A p.E135K (on ENST00000614775; = p.E34K on NM_001145432.1) | Missense Mutation (SNP) | VAF 92/169 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- SUPT3H | c.730G>T p.V244L (on ENST00000371460 / NM_181356.3; = p.V233L on NM_003599.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/184 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.702); called by muse, mutect2
- ZNF804A | c.3541C>A p.H1181N | Missense Mutation (SNP) | VAF 115/251 reads (46%) | SIFT tolerated (0.23); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- EYS | c.8829C>T p.L2943= (on ENST00000370621 / NM_001292009.1; = p.L2922= on NM_001142800.2) | Silent (SNP) | VAF 75/236 reads (32%) | called by muse, mutect2, varscan2
- FBXL4 | c.813C>T p.L271= | Silent (SNP) | VAF 170/331 reads (51%) | catalogued as rs146999462; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MAP3K14 | c.99G>T p.G33= | Silent (SNP) | VAF 47/226 reads (21%) | catalogued as COSV60923098; called by muse, mutect2, varscan2
- PCDHAC1 | c.2094C>T p.C698= | Silent (SNP) | VAF 58/114 reads (51%) | called by muse, mutect2, varscan2
- PTCH1 | c.2850C>T p.H950= | Silent (SNP) | VAF 15/34 reads (44%) | catalogued as rs200776583; ClinVar: likely benign; called by muse, mutect2, varscan2
- PXN | c.1300C>A p.R434= (on ENST00000228307 / NM_001080855.3; = p.R400= on NM_002859.4) | Silent (SNP) | VAF 20/40 reads (50%) | called by muse, mutect2, varscan2
- TTC21A | c.3201C>T p.H1067= | Silent (SNP) | VAF 36/79 reads (46%) | catalogued as rs1420466344; called by muse, mutect2, varscan2
- ZSCAN32 | c.846G>A p.P282= | Silent (SNP) | VAF 56/134 reads (42%) | catalogued as rs574771718; called by muse, mutect2, varscan2
- ANGPT2 | c.1330+808C>T | Intron (SNP) | VAF 16/32 reads (50%) | called by muse, varscan2
- AP000769.3 | chr11:65503673 del TGTC | 5'Flank (DEL) | VAF 56/338 reads (17%) | catalogued as rs751652054; called by mutect2, pindel, varscan2
- ARHGDIA | c.*176C>T | 3'UTR (SNP) | VAF 49/98 reads (50%) | called by muse, mutect2, varscan2
- ASIC2 | c.556-180591C>A | Intron (SNP) | VAF 37/80 reads (46%) | called by muse, mutect2, varscan2
- CDH17 | c.*104A>T | 3'UTR (SNP) | VAF 132/267 reads (49%) | called by muse, mutect2, varscan2
- CPSF2 | c.*730A>G | 3'UTR (SNP) | VAF 69/139 reads (50%) | catalogued as rs551530374; called by muse, mutect2, varscan2
- CRMP1 | chr4:5889639 C>G | 5'Flank (SNP) | VAF 14/505 reads (3%) | catalogued as COSV61482165; called by muse, mutect2
- DST-AS1 | n.139+7624C>T | Intron (SNP) | VAF 70/128 reads (55%) | called by muse, mutect2, varscan2
- EFNB2 | c.*2114A>T | 3'UTR (SNP) | VAF 45/90 reads (50%) | called by muse, mutect2, varscan2
- ENDOV | c.*89G>A | 3'UTR (SNP) | VAF 32/101 reads (32%) | catalogued as rs753710938, COSV72954244; called by muse, mutect2, varscan2
- FGB | c.115-537C>T | Intron (SNP) | VAF 8/138 reads (6%) | called by muse, mutect2
- GLI3 | c.*338A>T | 3'UTR (SNP) | VAF 89/232 reads (38%) | called by muse, mutect2, varscan2
- GRM6 | c.2125-701C>T | Intron (SNP) | VAF 19/45 reads (42%) | catalogued as rs1265735713; called by muse, mutect2, varscan2
- GSTM4 | chr1:109665392 C>T | 3'Flank (SNP) | VAF 76/157 reads (48%) | called by muse, mutect2, varscan2
- IGLC2 | c.*66C>T | 3'UTR (SNP) | VAF 52/157 reads (33%) | called by muse, mutect2, varscan2
- IGLON5 | c.*607C>T | 3'UTR (SNP) | VAF 70/131 reads (53%) | called by muse, mutect2, varscan2
- IL17RB | c.*85T>C | 3'UTR (SNP) | VAF 41/90 reads (46%) | catalogued as rs1339822704; called by muse, mutect2, varscan2
- LIFR | c.*2801G>C | 3'UTR (SNP) | VAF 51/100 reads (51%) | called by muse, mutect2, varscan2
- MFN1 | c.*125T>C | 3'UTR (SNP) | VAF 52/92 reads (57%) | called by muse, mutect2, varscan2
- MYG1 | c.-41C>G | 5'UTR (SNP) | VAF 8/24 reads (33%) | catalogued as COSV99670480; called by muse, mutect2, varscan2
- NFXL1 | c.*741T>A | 3'UTR (SNP) | VAF 8/179 reads (4%) | called by muse, mutect2
- PIK3C3 | c.-4T>C | 5'UTR (SNP) | VAF 60/148 reads (41%) | called by muse, mutect2, varscan2
- POU2F1 | c.-8-3206G>T | Intron (SNP) | VAF 20/168 reads (12%) | called by muse, mutect2, varscan2
- PPP2R1A | c.*104C>T | 3'UTR (SNP) | VAF 73/136 reads (54%) | called by muse, mutect2, varscan2
- PRLR | c.*7G>A | 3'UTR (SNP) | VAF 10/291 reads (3%) | catalogued as rs1383990122; called by muse, mutect2
- PTEN | c.-652G>A | 5'UTR (SNP) | VAF 11/22 reads (50%) | called by muse, mutect2
- PTGFRN | c.*3364C>T | 3'UTR (SNP) | VAF 4/28 reads (14%) | called by muse, mutect2
- SMU1 | c.*162C>T | 3'UTR (SNP) | VAF 64/167 reads (38%) | called by muse, varscan2
- SNRPE | c.*321C>G | 3'UTR (SNP) | VAF 17/51 reads (33%) | called by muse, mutect2, varscan2
- SRGAP3 | c.*1847C>T | 3'UTR (SNP) | VAF 19/84 reads (23%) | called by muse, mutect2, varscan2
- ST6GAL2 | c.*4599G>T | 3'UTR (SNP) | VAF 6/111 reads (5%) | called by muse, mutect2
- STPG2 | c.*2817C>A | 3'UTR (SNP) | VAF 101/206 reads (49%) | called by muse, mutect2, varscan2
- TCEANC2 | c.*2867delinsAG | 3'UTR (INS) | VAF 56/151 reads (37%) | called by pindel, varscan2*
- TECRL | chr4:64276873 G>T | 3'Flank (SNP) | VAF 51/92 reads (55%) | called by muse, mutect2, varscan2
- TET2 | c.*3021G>A | 3'UTR (SNP) | VAF 57/105 reads (54%) | called by muse, mutect2, varscan2
- TMEM151B | c.*394G>A | 3'UTR (SNP) | VAF 58/110 reads (53%) | catalogued as rs1053748664; called by muse, mutect2, varscan2
- TMEM199 | c.*2229C>T | 3'UTR (SNP) | VAF 15/70 reads (21%) | catalogued as rs894433333; called by muse, mutect2, varscan2
- TRPM3 | c.1154+7695C>T | Intron (SNP) | VAF 188/425 reads (44%) | called by muse, mutect2, varscan2
- TRPS1 | chr8:115411963 C>A | 3'Flank (SNP) | VAF 64/174 reads (37%) | called by muse, mutect2, varscan2
- USP40 | c.268-1104G>T | Intron (SNP) | VAF 50/118 reads (42%) | called by muse, mutect2
- ZNF19 | c.274+36G>A | Intron (SNP) | VAF 96/214 reads (45%) | catalogued as rs779978690; called by muse, mutect2, varscan2
